Somatic mutation profile of tumor specimen C3N-00578-04 (aliquot CPT0069360006) from CPTAC case C3N-00578, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 48.8 years (17,824 days).
Specimen C3N-00578-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3daabba-d29e-42e9-b92b-a1a974925506.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00578-71 (Blood Derived Normal), aliquot CPT0069450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61fd7f37-f79c-48d4-bc95-bf547634b6ca

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Intron 3, RNA 2, 5'UTR 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1478G>A p.R493H (on ENST00000359125 / NM_172107.4; = p.R465H on NM_004518.6) | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs774040213, COSV60544845; called by muse, mutect2
- KCNS2 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs769042324, COSV99751561; called by muse, mutect2, varscan2
- KRT33A | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs143392985; called by muse, mutect2
- NLGN4X | c.1206C>A p.F402L | Missense Mutation (SNP) | VAF 140/378 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99323541; called by muse, mutect2, varscan2
- OR5M3 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as rs1406730292, COSV56566078; called by muse, mutect2, varscan2
- PTPN1 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV100860618; called by muse, mutect2, varscan2
- SGIP1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.055); catalogued as rs372902905; called by muse, mutect2, varscan2
- SPEG | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.067); catalogued as rs1156992455, COSV56673788; called by muse, mutect2, varscan2
- USP4 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV55540632; called by muse, mutect2, varscan2
- WNT9A | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs770228799; called by muse, mutect2, varscan2
- AJAP1 | c.1069T>A p.S357T | Missense Mutation (SNP) | VAF 30/725 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CELSR3 | c.4502A>G p.Q1501R | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- DHX30 | c.185G>A p.G62E (on ENST00000445061 / NM_138615.3; = p.G23E on NM_014966.3) | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ECT2 | c.919A>G p.R307G (on ENST00000392692 / NM_001349098.2; = p.R276G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EML5 | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2
- FEN1 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 143/703 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRFN4 | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 79/324 reads (24%) | called by muse, mutect2, varscan2
- PCDHA8 | c.2249A>G p.Y750C | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- POU2F2 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, varscan2
- RAG1 | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 21/524 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.031); called by muse, mutect2
- RPA4 | c.506A>C p.D169A | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.175); called by muse, mutect2
- SALL1 | c.3043G>T p.A1015S | Missense Mutation (SNP) | VAF 69/1546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC17A4 | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- TAF1 | c.1571A>G p.K524R (on ENST00000373790 / NM_138923.4; = p.K545R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TDRKH | c.908A>T p.H303L | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TRPM1 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 48/425 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBED1 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 107/534 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- C19orf44 | c.1770C>T p.L590= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as rs757138878; called by muse, mutect2, varscan2
- GIPR | c.54G>A p.L18= | Silent (SNP) | VAF 50/300 reads (17%) | called by muse, varscan2
- ME1 | c.273A>T p.T91= | Silent (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1767C>A p.T589= | Silent (SNP) | VAF 82/501 reads (16%) | called by muse, mutect2, varscan2
- SLC12A6 | c.1083A>T p.G361= (on ENST00000354181 / NM_001365088.1; = p.G310= on NM_005135.2) | Silent (SNP) | VAF 122/431 reads (28%) | called by muse, mutect2, varscan2
- TRIB1 | c.813G>A p.G271= | Silent (SNP) | VAF 122/469 reads (26%) | called by muse, mutect2, varscan2
- XDH | c.1077C>T p.S359= | Silent (SNP) | VAF 156/596 reads (26%) | catalogued as rs747850652, COSV101051973; called by muse, mutect2, varscan2
- DLST | c.442+21G>C | Intron (SNP) | VAF 39/265 reads (15%) | called by muse, mutect2, varscan2
- FAM74A3 | n.230C>T | RNA (SNP) | VAF 59/1368 reads (4%) | catalogued as rs138479120; called by muse, mutect2
- FAM86DP | n.560A>C | RNA (SNP) | VAF 130/648 reads (20%) | called by mutect2, varscan2
- GIPR | c.-40G>C | 5'UTR (SNP) | VAF 76/401 reads (19%) | called by muse, varscan2
- KLC1 | c.1651-7099C>A | Intron (SNP) | VAF 114/312 reads (37%) | catalogued as rs770229889; called by muse, mutect2, varscan2
- MFRP | chr11:119346306 C>A | 5'Flank (SNP) | VAF 24/686 reads (3%) | called by muse, mutect2
- PSMB7 | c.511+8530A>G | Intron (SNP) | VAF 63/211 reads (30%) | catalogued as rs1485233671; called by muse, mutect2, varscan2
- SLC17A5 | c.-25G>T | 5'UTR (SNP) | VAF 72/414 reads (17%) | called by muse, mutect2, varscan2
